CPTAC case C3L-03462 — Bronchus and lung — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/94bb61ca-3e9c-4754-b20f-a5eb4b3cd5dd

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1956; Vital status: Dead; Days to death: 1,509 days (4.1 years); Year of death: 2022; Cause of death: Cancer Related; Country of birth: United States.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Upper lobe, lung; Age at diagnosis: 61.5 years (22,465 days); Year of diagnosis: 2018; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Residual disease: R0; Last known disease status: With tumor; Days to last known disease status: 1,509 days (4.1 years); Progression or recurrence: no; Days to last follow up: 1,509 days (4.1 years); Tumor focality: Multifocal.
   Pathology details: Greatest tumor dimension: 2.6 cm; Lymph node involvement: Positive; Lymph nodes positive: 3; Lymph nodes tested: 14; Margin status: Uninvolved.

Follow-up (6 entries)
- Days to follow up: 764 days (2.1 years); Disease response: Tumor Free; ECOG performance status: 0.
- Days to follow up: 1,051 days (2.9 years); Disease response: Progressive Disease; Progression or recurrence: Yes; Days to recurrence: 861 days (2.4 years).
- Days to follow up: 1,051 days (2.9 years); Disease response: With Tumor.
- Days to follow up: 1,436 days (3.9 years); Disease response: With Tumor.
- Days to follow up: 1,509 days (4.1 years); Disease response: With Tumor.
- Follow-up contact recording only the day: day 436.

Other clinical attributes
- Weight: 85.28 kg; Height: 182.88 cm; BMI: 25.49.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 66.2; Cigarettes per day: 27; Tobacco smoking onset year: 1968; Tobacco smoking quit year: 2017; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker; Exposure duration years: 49; Secondhand smoke as child: Yes; Type of smoke exposure: Smoke exposure, NOS.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-03462-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -8 days; Initial weight: 163 mg; Time between excision and freezing: 26 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-03462-24: Section location: Right Upper Lobe; Percent tumor nuclei: 65; Percent necrosis: 2.
- Sample C3L-03462-03: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -8 days; Initial weight: 43 mg; Time between excision and freezing: 26 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-03462-04: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -8 days; Initial weight: 105 mg; Time between excision and freezing: 26 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-03462-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -8 days; Method of sample procurement: Blood Draw.
